Gene-level copy-number profile of tumor specimen HTMCP-03-06-02157-01B from CGCI case HTMCP-03-06-02157, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G3.
Specimen HTMCP-03-06-02157-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 15c189a6-6758-487b-8d23-372a1cb72ad3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02157-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/273d2b7c-2a32-43ae-b575-37279676e6b6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,917; copy number 2: 18,011; copy number 3: 15,885; copy number 4: 14,726; copy number 5: 4,997; copy number 6: 1,138; copy number 7: 704; copy number 8: 335; copy number 9: 72; copy number 10: 351; copy number 11: 47; copy number 12: 78; copy number 13: 28; copy number 14: 3; copy number 16: 77; copy number 17: 7; copy number 19: 1; copy number 20: 4; copy number 27: 5.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:45,480,030–45,480,136, 1 gene: RNU6-931P.
- chr14:68,338,728–68,422,196, 2 genes (within-gene range 0–2): AL122013.1, PPIAP6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,683 genes in 125 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–827,796, 51 genes, copy number 6 (within-gene range 3–6): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AL669831.3, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16, CICP3, AL669831.1, RNU6-1199P, AL669831.2, LINC01409, AL669831.6, AL669831.4, FAM87B.
- chr1:155,913,045–156,299,307, 27 genes, copy number 6: KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL.
- chr1:248,691,760–248,937,043, 13 genes, copy number 5–12: LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:111,887,914–117,139,775, 95 genes, copy number 5 (broad region; genes not listed).
- chr2:131,361,111–169,096,167, 446 genes, copy number 5–6 (broad region; genes not listed).
- chr3:48,094,801–48,430,086, 18 genes, copy number 6: RN7SL664P, AC124916.1, CDC25A, SNRPFP4, RNU7-128P, NDUFB1P1, MIR4443, CAMP, ZNF589, MRPS18AP1, Y_RNA, NME6, FCF1P2, SPINK8, MIR2115, FBXW12, RN7SL321P, PLXNB1.
- chr5:58,198–443,160, 17 genes, copy number 5–19 (within-gene range 3–19): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1.
- chr5:140,107,777–140,594,570, 23 genes, copy number 6 (within-gene range 3–6): PURA, IGIP, AC011379.2, CYSTM1, AC011379.1, PFDN1, HBEGF, AC008438.2, SLC4A9, AC008438.1, RNU4-14P, ANKHD1, ANKHD1-EIF4EBP3, AC011399.1, SRA1, EIF4EBP3, APBB3, AC116353.5, MIR6831, SLC35A4, AC116353.6, AC116353.1, HAUS1P1.
- chr5:181,147,586–181,342,213, 21 genes, copy number 5: OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr6:12,716,554–32,473,500, 662 genes, copy number 5–12 (broad region; genes not listed).
- chr6:32,549,940–76,662,770, 757 genes, copy number 5–13 (broad region; genes not listed).
- chr6:95,504,182–107,824,317, 114 genes, copy number 5–16 (broad region; genes not listed).
- chr6:109,288,440–111,259,034, 41 genes, copy number 10–27: AL359711.1, PTCHD3P3, RNY3P11, RPL7P28, CD164, AL359711.2, PPIL6, SMPD2, MICAL1, ZBTB24, AL109947.1, AK9, FIG4, GPR6, WASF1, CDC40, METTL24, AL050350.1, DDO, SLC22A16, RN7SL617P, AC002464.1, AL512430.3, AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6, RPF2, GSTM2P1, SLC16A10, RNU6-960P, AL360227.1.
- chr6:111,660,332–116,829,083, 73 genes, copy number 10 (broad region; genes not listed).
- chr6:117,633,706–144,853,034, 369 genes, copy number 5–16 (broad region; genes not listed).
- chr7:2,251,770–2,775,500, 14 genes, copy number 6 (within-gene range 4–6): SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1.
- chr9:111,327,483–119,369,435, 116 genes, copy number 5 (broad region; genes not listed).
- chr10:42,149,310–133,778,699, 1,616 genes, copy number 5–8 (broad region; genes not listed).
- chr11:130,789,231–135,075,908, 56 genes, copy number 5–20: PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2, NTM, RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1, AP000844.2, AP000844.1, NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.1, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02684.
- chr12:12,310–277,123, 14 genes, copy number 6–11: DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4.
- chr13:113,648,804–114,337,626, 21 genes, copy number 6–17: ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1, CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:103,184,204–103,562,831, 20 genes, copy number 5–7 (within-gene range 3–7): GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13, RAP2CP1, AL138976.1, AL138976.2, EIF5, SNORA28, HMGB3P26, RPSAP5, MARK3, RPL10AP1, CKB, AL133367.1, TRMT61A, RNU7-160P, AL139300.2, BAG5.
- chr14:106,556,936–106,879,812, 51 genes, copy number 6–13: IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:39,921,042–40,326,715, 26 genes, copy number 5: GPR176-DT, Y_RNA, EIF2AK4, H3P38, SRP14, SRP14-AS1, AC021755.2, AC021755.3, BMF, BMF-AS1, AC021755.1, BUB1B, PAK6, BUB1B-PAK6, AC020658.4, AC020658.3, AC020658.7, C15orf56, AC020658.6, PLCB2, ANKRD63, AC020658.5, PLCB2-AS1, AC020658.1, AC020658.2, INAFM2.
- chr15:101,803,509–101,979,093, 16 genes, copy number 7: OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:11,555–272,183, 26 genes, copy number 5–8 (within-gene range 3–8): DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG, NPRL3, Z69720.1, Z69666.1, HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1, Z69706.1, LUC7L, Z69890.1, FAM234A.
- chr16:89,873,570–90,222,851, 21 genes, copy number 7–12: TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr17:17,972,813–31,382,116, 485 genes, copy number 5–13 (within-gene range 3–13) (broad region; genes not listed).
- chr17:34,579,487–40,017,813, 237 genes, copy number 5–11 (broad region; genes not listed).
- chr18:45,034–12,448,205, 277 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr18:20,946,906–21,893,996, 26 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P.
- chr19:8,052,767–10,933,535, 147 genes, copy number 5–8 (broad region; genes not listed).
- chr19:11,089,462–16,104,254, 300 genes, copy number 5–8 (broad region; genes not listed).
- chr19:16,134,028–20,571,095, 241 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:21,554,640–24,163,425, 117 genes, copy number 6 (broad region; genes not listed).
- chr19:58,228,594–58,605,223, 50 genes, copy number 6–12: ZNF544, AC020915.4, AC020915.2, AC020915.1, ZNF8, ZNF8-ERVK3-1, ERVK3-1, AC010642.2, AC010642.1, ZSCAN22, MIR6806, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr20:87,250–2,177,038, 65 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr22:15,282,557–23,954,042, 511 genes, copy number 5 (broad region; genes not listed).
- chr22:42,364,390–42,777,296, 17 genes, copy number 6: LINC01315, NFAM1, AL022316.1, SERHL, RRP7A, SERHL2, RRP7BP, RN7SKP80, RNU6-513P, POLDIP3, RNU12, Z93241.1, CYB5R3, ATP5MGL, A4GALT, Y_RNA, RPL5P34.
- chr22:50,343,304–50,801,309, 30 genes, copy number 6–12 (within-gene range 3–12): PPP6R2, SBF1, ADM2, MIOX, LMF2, NCAPH2, SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 1,917. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
